Gene-level copy-number profile of tumor specimen TCGA-56-6545-01A from TCGA case TCGA-56-6545, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.8 years (28,400 days).
Specimen TCGA-56-6545-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.65f86178-0888-48df-8272-26083aef50b9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-56-6545-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/96b290fe-4f04-465a-9ef9-62d9a9246728

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 140; copy number 2: 17,200; copy number 3: 19,227; copy number 4: 16,526; copy number 5: 3,099; copy number 6: 472; copy number 7: 2,395; copy number 8: 123; copy number 9: 58; copy number 10: 136; copy number 11: 244; copy number 12: 16; copy number 14: 16; copy number 15: 26; copy number 25: 48; copy number 27: 7; copy number 28: 50; copy number 56: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-56-6545-01A-11D-1816-01): tumor purity 0.32, ploidy 3.31, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:88,883,328–91,164,437, 15 genes (within-gene range 0–3): MEF2C-AS1, AC074131.1, LINC02161, AC113167.1, MIR3660, LINC01339, AC099554.1, AC093510.2, CETN3, AC093510.1, MBLAC2, POLR3G, LYSMD3, ADGRV1, TMEM251P1.
- chr5:108,747,841–109,196,841, 1 gene (within-gene range 0–3): FER.
- chr5:108,891,437–109,409,974, 7 genes: Y_RNA, AC109481.1, RNU6-47P, GJA1P1, AC116428.1, AC008467.1, PJA2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,133 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:53,470,447–66,200,373, 222 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr2:85,837,120–87,636,740, 45 genes, copy number 9 (within-gene range 2–9): ST3GAL5, ST3GAL5-AS1, AC012511.1, AC012511.2, POLR1A, PTCD3, SNORD94, IMMT, Y_RNA, MIR4779, AC009309.1, MRPL35, REEP1, U8, AC009408.1, KDM3A, CHMP3, RNF103-CHMP3, RNU6-640P, AC015971.1, RNF103, RMND5A, CD8A, CD8B, ANAPC1P1, AC111200.1, RGPD1, WBP1P1, NDUFB4P5, PLGLB1, ANAPC1P2, ANAPC1P2, AC092651.1, AC092651.2, ANAPC1P3, AC083899.1, MIR4771-1, CENPNP1, LINC01955, DBF4P3, AC068279.2, IGKV3OR2-268, AC068279.1, LINC01943, CYTOR.
- chr2:87,477,495–87,566,764, 2 genes, copy number 9: AC133644.1, PAFAH1B1P1.
- chr3:168,249,522–170,860,993, 53 genes, copy number 10 (within-gene range 5–10): EGFEM1P, AC124893.1, RNU2-20P, MIR551B, RPSAP33, RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5.
- chr3:171,843,349–173,336,965, 24 genes, copy number 8 (within-gene range 6–8): TMEM212, TMEM212-IT1, AC055714.1, FNDC3B, RPS27AP8, RN7SL141P, AC092964.1, BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1, NCEH1, AC007919.2, RNU6-547P, AC108667.2, ECT2, SNORA72, RNU4-4P, ATP5MC1P4, AC108667.1, SPATA16, AC068759.1.
- chr3:173,644,231–173,644,711, 1 gene, copy number 8: AC092967.1.
- chr3:176,415,439–192,767,764, 303 genes, copy number 7–10 (within-gene range 5–10) (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 7 (broad region; genes not listed).
- chr6:69,672,757–70,664,279, 16 genes, copy number 12: LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15, COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6.
- chr7:53,035,633–56,176,412, 70 genes, copy number 10–28 (broad region; genes not listed).
- chr7:65,335,174–68,036,917, 74 genes, copy number 15–25 (broad region; genes not listed).
- chr7:92,560,758–93,911,265, 21 genes, copy number 27–56 (within-gene range 4–56): FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT.
- chr7:98,794,718–100,723,700, 110 genes, copy number 11 (broad region; genes not listed).
- chr8:127,253,213–127,482,139, 5 genes, copy number 8 (within-gene range 4–8): AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2.
- chr10:18,513,115–18,659,285, 3 genes, copy number 9 (within-gene range 5–9): AL450384.2, AL450384.1, NSUN6.
- chr11:10,725,903–13,924,863, 64 genes, copy number 11 (broad region; genes not listed).
- chr11:57,299,638–57,661,865, 23 genes, copy number 10: TNKS1BP1, AP000781.1, SSRP1, P2RX3, PRG3, PRG2, AP000781.2, SLC43A3, RNA5SP341, RN7SKP259, RTN4RL2, AP002893.1, SLC43A1, RN7SL605P, TIMM10, SMTNL1, UBE2L6, RPS4XP13, SERPING1, AP000662.1, MIR130A, YPEL4, CLP1.
- chr12:71,582,293–71,594,404, 2 genes, copy number 14: AC078860.3, AC078860.2.
- chr16:49,066,567–90,222,851, 1,075 genes, copy number 7 (broad region; genes not listed).
- chr19:54,351,384–58,605,223, 310 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 140. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
